Gene-level copy-number profile of tumor specimen TCGA-FV-A2QR-01A from TCGA case TCGA-FV-A2QR, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1.
Specimen TCGA-FV-A2QR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.74f79907-d471-4348-9eb8-8a787006109f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FV-A2QR-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e6aaf71b-b98b-4a46-8806-8cb9312751a1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,768; copy number 2: 45,726; copy number 3: 3,458; copy number 4: 1,263; copy number 5: 390; copy number 6: 1,199.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FV-A2QR-01A-11D-A20V-01): tumor purity 0.8, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,589 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,019,656–147,179,622, 8 genes, copy number 5: AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1.
- chr1:147,175,351–147,243,050, 2 genes, copy number 5 (within-gene range 2–5): FMO5, CCT8P1.
- chr1:149,754,301–194,931,310, 1,199 genes, copy number 6 (broad region; genes not listed).
- chr7:70,837,738–94,834,447, 378 genes, copy number 5 (broad region; genes not listed).
- chr7:95,018,163–95,018,554, 2 genes, copy number 5: HINT1P2, AC002429.1.

Autosomal genes at a single copy (total copy number 1): 6,436. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
